Surgical pathology report (de-identified scan), TCGA case TCGA-J4-AAU2, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-AAU2-01A (Primary Tumor).

[page 1 of 4]
Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-NFS-
- B. LEFT PELVIC LYMPH NODES-FS-
- C. PROSTATE GLAND-

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JN 5/28/14

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-NFS-
LYMPH NODES, NO TUMOR SEEN..
- B. LEFT PELVIC LYMPH NODES-FS-
SEE PART A.
- C. PROSTATE GLAND-

ADENOCARCINOMA OF PROSTATE WITH MICROSCOPIC INVOLVEMENT OF THE
BLADDER MARGIN

TUMOR SITE: RIGHT AND LEFT SIDES.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 34 GRAMS.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10.

TNM STAGE: pT3a, pN0, pMX.

PERINEURAL INVASION: NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

Prepared for

[page 2 of 4]
POSITIVE INKED MARGIN: BLADDER NECK, FOCAL.
OTHER MARGINS ARE CLEAR.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT PELVIC LYMPH NODES: FOUR LYMPH NODES. NO TUMOR SEEN.

FS Performed by

(Frozen Section Signed

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "left pelvic lymph nodes-NFS" consist of a 2.5 cm aggregate of tan previously sectioned fatty tissue. No palpable masses are identified. The entire specimen is submitted in A1-A2.

B. Received in formalin labeled with the patient's name and "left pelvic lymph nodes FS" consists of four frozen section tissue remnants measuring from 1.5 cm down to 0.6 cm. Entirely submitted in B1.

C. Received in formalin labeled with the patient's name and "prostate gland" consists of a radical prostatectomy which includes a 34 gram prostate gland with attached seminal vesicles with small segments of vas deferentia. The prostate measures 5 x 3.5 x 3.5 cm and has a shaggy capsule where it is disrupted at the bladder margin. The specimen is inked black on the left and blue on the right. The right seminal vesicle measures 4 x 1 x 1.0 cm. The right vas deferens measures 3.0 cm in length. The left seminal vesicle measures 4.5 x 1 x 1.0 cm. The left vas deferens measures 2.5 cm. The inferior prostate is sectioned transversely and removed from the rest of the specimen and then sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicle, vas deferentia show no gross abnormalities. Section code is as follows: inferior prostate demonstrating apical margins submitted entirely anterior to posterior in C1-C6; bladder margin C7-C8; complete section of mid gland anterior

Prepared for

[page 3 of 4]
C9-C10; posterior aspect C11-C12; complete section of upper third of gland anterior C13-C14; posterior aspect C15-C16; remainder of posterior gland entirely submitted in C17-C21; C22=right seminal vesicle vas deferens; C23=left seminal vesicle vas deferens

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1

H&E X1

A. AA ROUTINE H&E X1 BLOCK.2

H&E X1

B. AA ROUTINE H&E X1 BLOCK

H&E X1

C. AA ROUTINE H&E X1 BLOCK.1

H&E X1

C. AA ROUTINE H&E X1 BLOCK.2

H&E X1

C. AA ROUTINE H&E X1 BLOCK.3

H&E X1

C. AA ROUTINE H&E X1 BLOCK.4

H&E X1

C. AA ROUTINE H&E X1 BLOCK.5

H&E X1

C. AA ROUTINE H&E X1 BLOCK.6

H&E X1

C. AA ROUTINE H&E X1 BLOCK.7

H&E X1

C. AA ROUTINE H&E X1 BLOCK.8

H&E X1

C. AA ROUTINE H&E X1 BLOCK.9

H&E X1

C. AA ROUTINE H&E X1 BLOCK.10

H&E X1

C. AA ROUTINE H&E X1 BLOCK.11

H&E X1

C. AA ROUTINE H&E X1 BLOCK.12

H&E X1

C. AA ROUTINE H&E X1 BLOCK.13

H&E X1

C. AA ROUTINE H&E X1 BLOCK.14

H&E X1

C. AA ROUTINE H&E X1 BLOCK.15

H&E X1

C. AA ROUTINE H&E X1 BLOCK.16

[page 4 of 4]
H&E X1
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
C. AA ROUTINE H&E X1 BLOCK.21
H&E X1
C. AA ROUTINE H&E X1 BLOCK.22
H&E X1
C. AA ROUTINE H&E X1 BLOCK.23
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 87f73fcc-cb11-40e3-87cd-07edd88b3d5f (TCGA-J4-AAU2.D4358B1C-AB27-4B36-ABF9-B4EE2E504493.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).